CGCI case HTMCP-02-15-01098 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eda80da3-cf75-43d1-b853-37927e76cf05

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Main bronchus; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 58.6 years (21,420 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical N: N3; AJCC clinical M: M1a; AJCC clinical stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 140 days; Sites of involvement: Bronchus.
   Pathology details: Lymph node involved site: Axillary; Lymph nodes positive: 1; Lymph nodes tested: 1.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 140 days; Disease response: With Tumor.
- Follow-up contacts recording only the day: day -3,523, day 0.

Molecular and laboratory tests
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day -3,523: Risk factors: HIV/AIDS.
- Day -3,523: Comorbidities: HIV/AIDS.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 0: Weight: 70.31 kg; Height: 154.94 cm; BMI: 29.3; CD4 count: 528; Haart treatment indicator: Yes; HIV viral load: 40.
- Day 0: Risk factors: Hepatitis B Infection.
- Day 140: Nadir CD4 count: 345.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 10; Tobacco smoking quit year: 2017.

Biospecimens (3 samples)
- Sample HTMCP-02-15-01098-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-15-01098-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-15-01098-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Adenocarcinoma, Not Otherwise Specified; Tumor status: With tumor; Tobacco smoking age started: 39; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No; Tobacco smoking history indicator: 4; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Bronchus.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 2008; Hbv test results: Positive; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact; History relevant infectious diagnosis: Syphilis and Hepatitis B.
- Primary pathology: Lymph nodes examined: Yes; Days from index date to tumor sample procurement: -6; Other pos node location: Left Axillary Lymph Node.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-15-01098-01A-02E-14095:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-15-01098-01A-02S-14095:
- % tumour top: 80
- % tumour bottom: 80
